TCGA case TCGA-XE-AANU — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/18ec59af-5c0e-40ed-83ef-7834366c4bbe

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 29 years; Year of birth: 1980; Vital status: Alive.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 29.1 years (10,616 days); Year of diagnosis: 2009; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,813 days (5.0 years); Ajcc serum tumor markers: S0.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,813 days (5.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Lactate Dehydrogenase 192; Alpha Fetoprotein 28.3; Human Chorionic Gonadotropin 41.3.
- Day 1,813: Lactate Dehydrogenase 126; Alpha Fetoprotein 1.3.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Undescended testis history: No.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Natural Mother; Relationship primary diagnosis: Skin Cancer.
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Cancer.
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Grandfather; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XE-AANU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 290 mg.
  Slide TCGA-XE-AANU-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 0.
- Sample TCGA-XE-AANU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XE-AANU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
